Somatic mutation profile of tumor specimen TCGA-62-8399-01A (aliquot TCGA-62-8399-01A-21D-2323-08) from TCGA case TCGA-62-8399, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.8 years (22,952 days).
Specimen TCGA-62-8399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87c3bd07-208e-40e5-b427-f4f917260392.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-8399-10A (Blood Derived Normal), aliquot TCGA-62-8399-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0121a6c3-c7ae-4619-b07a-27bb28541478

The open-access MAF lists 560 somatic variants for this specimen: 430 protein-altering or splice-affecting, 120 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 374, Silent 120, Nonsense Mutation 35, Splice Site 9, Frame Shift Del 7, Intron 6, Frame Shift Ins 3, RNA 2, 5'UTR 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 60/110 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs11575996, CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; called by muse, mutect2, varscan2
- ABCB10 | c.1897C>G p.L633V | Missense Mutation (SNP) | VAF 127/479 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV100747902; called by muse, mutect2, varscan2
- ABCG4 | c.1193C>G p.S398C | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100266662; called by muse, mutect2, varscan2
- ABCG5 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV53210935, COSV53214726; called by muse, mutect2, varscan2
- ABLIM3 | c.1593G>A p.M531I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs780531168, COSV100448239; called by muse, mutect2, varscan2
- AC011448.1 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99364153, COSV99364527; called by muse, mutect2, varscan2
- AC131160.1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); catalogued as COSV100226150, COSV57701900; called by muse, mutect2, varscan2
- AC134980.2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100171582, COSV60909011; called by muse, mutect2, varscan2
- ACVR2A | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99604300; called by muse, mutect2, varscan2
- ADAD1 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56642550, COSV99635398; called by muse, mutect2, varscan2
- ADAL | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 36/90 reads (40%) | catalogued as COSV101052513; called by muse, mutect2, varscan2
- ADAM18 | c.1541C>A p.P514Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV55846208, COSV99695314; called by muse, mutect2, varscan2
- ADAMTS5 | c.829del p.A277Rfs*16 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV53178217; called by mutect2, pindel, varscan2
- ADGRE5 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV54413761; called by muse, mutect2, varscan2
- ADGRE5 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); catalogued as COSV99662821; called by muse, mutect2, varscan2
- AIM2 | c.542T>G p.V181G | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100931050; called by muse, mutect2
- ANKK1 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1312514821, COSV100392783; called by muse, mutect2, varscan2
- ANKRD12 | c.3295A>G p.K1099E | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100041047; called by muse, mutect2, varscan2
- AP1B1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100434502; called by muse, mutect2
- APOLD1 | c.760C>G p.R254G (on ENST00000326765 / NM_001130415.2; = p.R223G on NM_030817.3) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs180902175, COSV100458557; called by muse, mutect2, varscan2
- ARAP2 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.009); catalogued as COSV100394383; called by muse, mutect2, varscan2
- ARID4B | c.2569A>C p.S857R | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV99935376; called by muse, mutect2, varscan2
- ARSD | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101144360; called by muse, mutect2
- ASAP2 | c.2917G>A p.V973M | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1175223446, COSV53005790; called by muse, mutect2, varscan2
- ASB17 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99407755, COSV99407871, COSV99407958; called by muse, mutect2, varscan2
- ATP2A1 | c.659T>A p.L220* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as COSV100837233; called by muse, mutect2, varscan2
- ATP6V0D2 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.586); catalogued as rs1343831181, COSV53413606, COSV53416972; called by muse, mutect2, varscan2
- ATP7B | c.404C>G p.S135* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99666270; called by muse, mutect2
- BAIAP3 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100181302; called by muse, mutect2, varscan2
- BBX | c.1670G>T p.S557I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100361324; called by muse, mutect2, varscan2
- BCAN | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1245040424, COSV61258287; called by muse, mutect2, varscan2
- BICC1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs201753164, COSV65856907; called by muse, mutect2, varscan2
- BST2 | c.131T>A p.F44Y | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV99392060; called by muse, mutect2, varscan2
- C12orf50 | c.1044T>G p.N348K | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100072145; called by muse, mutect2, varscan2
- C16orf89 | c.471G>C p.E157D | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs1308687426, COSV100280779, COSV60125681; called by muse, mutect2, varscan2
- C4orf50 | c.679G>A p.G227R (on ENST00000324058; = p.G1459R on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs115887613, COSV60689147; called by muse, mutect2, varscan2
- C6orf58 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 63/141 reads (45%) | catalogued as COSV100314825; called by muse, mutect2, varscan2
- CACNA1B | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 89/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764637506, COSV99496510; called by muse, mutect2, varscan2
- CAMSAP2 | c.1274G>C p.G425A (on ENST00000236925 / NM_001297707.2; = p.G414A on NM_203459.3) | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99373163; called by muse, mutect2, varscan2
- CAPG | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs749388241, COSV55707706; called by muse, mutect2, varscan2
- CASP2 | c.989A>T p.D330V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100130950; called by muse, mutect2, varscan2
- CCDC103 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99493187; called by muse, mutect2, varscan2
- CCDC74A | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99723692; called by muse, mutect2, varscan2
- CD22 | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV50049496, COSV99323062; called by muse, mutect2, varscan2
- CDH10 | c.1321C>A p.L441I | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52577280, COSV52580482; called by muse, mutect2, varscan2
- CDH13 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51861958; called by muse, mutect2, varscan2
- CDH2 | c.2402T>A p.I801N | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); catalogued as COSV99296394; called by muse, mutect2, varscan2
- CDH23 | c.4974G>T p.Q1658H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.393); catalogued as COSV99820146; called by muse, mutect2, varscan2
- CDKN2D | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.618); catalogued as COSV100224767, COSV100224846; called by muse, mutect2, varscan2
- CES5A | c.768C>G p.I256M | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV99307345; called by muse, mutect2, varscan2
- CFAP251 | c.1321-1G>C p.X441_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99995966; called by muse, mutect2, varscan2
- CFAP54 | c.8251C>G p.L2751V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100733075; called by muse, mutect2, varscan2
- CFAP74 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV54570122; called by muse, mutect2
- CFH | c.1813G>C p.G605R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100809258; called by muse, mutect2, varscan2
- CHD1L | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100787248, COSV100787401; called by muse, mutect2, varscan2
- CHD6 | c.7664C>G p.S2555* | Nonsense Mutation (SNP) | VAF 48/275 reads (17%) | catalogued as COSV100950839, COSV100951161; called by muse, mutect2, varscan2
- CHIT1 | c.125T>A p.L42Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99705178; called by muse, mutect2, varscan2
- CHRND | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV99285658; called by muse, mutect2, varscan2
- CHTF18 | c.960G>T p.R320S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV99135696; called by muse, mutect2, varscan2
- CIART | c.747C>A p.H249Q | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as COSV99290225; called by muse, mutect2, varscan2
- CIART | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as COSV99290227; called by muse, mutect2, varscan2
- CILP2 | c.3271G>T p.E1091* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99364529; called by muse, mutect2, varscan2
- CMTM5 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.673); catalogued as COSV100197996; called by muse, mutect2, varscan2
- CNDP1 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs138535410; called by muse, mutect2, varscan2
- CNOT1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100408983; called by muse, mutect2, varscan2
- CNTNAP2 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100664817; called by muse, mutect2, varscan2
- COL11A1 | c.4364C>A p.P1455H | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100615903; called by muse, mutect2, varscan2
- COL19A1 | c.1086G>C p.L362F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.301); catalogued as COSV100505934, COSV59564451; called by muse, mutect2, varscan2
- COL3A1 | c.2131G>T p.G711C | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM026026, COSV100482809; called by muse, mutect2, varscan2
- COL5A2 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66415326; called by muse, mutect2, varscan2
- COL6A2 | c.627C>G p.H209Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs545218705, COSV100153277, COSV56012232; called by muse, mutect2, varscan2
- COL6A2 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373392391; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.8495C>A p.P2832H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99866192; called by muse, mutect2
- CPA6 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913220; called by muse, mutect2, varscan2
- CPXM2 | c.1470A>C p.E490D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV53864111; called by muse, mutect2, varscan2
- CREB3L2 | c.797T>A p.L266Q | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100381770; called by muse, mutect2, varscan2
- CTAGE1 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs374980447, COSV101194499; called by muse, mutect2
- CXXC1 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV53274668; called by muse, mutect2, varscan2
- CYP4V2 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs202202084, COSV101114814; called by muse, mutect2, varscan2
- DCAF12L2 | c.1320G>T p.E440D | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.991); catalogued as COSV100758531; called by muse, mutect2, varscan2
- DCAF6 | c.1796C>G p.S599C (on ENST00000312263 / NM_001349778.1; = p.S619C on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.417); catalogued as COSV100394123; called by muse, mutect2, varscan2
- DCAF6 | c.1916C>T p.S639L (on ENST00000312263 / NM_001349778.1; = p.S659L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100394124, COSV56576311; called by muse, mutect2, varscan2
- DCLRE1A | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs1010326820, COSV100800300; called by muse, mutect2, varscan2
- DDA1 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.617); catalogued as COSV63290030; called by muse, mutect2
- DDHD2 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.14); catalogued as rs1338217198, COSV68157357; called by muse, mutect2, varscan2
- DISP1 | c.3007A>C p.T1003P | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52660601; called by muse, mutect2, varscan2
- DLGAP2 | c.1748A>G p.D583G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101421589; called by muse, mutect2, varscan2
- DNAH10 | c.1308G>C p.W436C (on ENST00000409039; = p.W375C on NM_207437.3) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292151; called by muse, mutect2, varscan2
- DNAH10 | c.13201C>A p.Q4401K (on ENST00000409039; = p.Q4340K on NM_207437.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99435413; called by muse, mutect2, varscan2
- DNAH11 | c.6706G>T p.G2236C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100178502; called by muse, mutect2, varscan2
- DNAH5 | c.7330G>C p.E2444Q | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV99447897; called by muse, mutect2, varscan2
- DNAH5 | c.6723G>T p.W2241C | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99447900; called by muse, mutect2, varscan2
- DNAJC21 | c.1570-1G>C p.X524_splice | Splice Site (SNP) | VAF 14/182 reads (8%) | catalogued as COSV100331329; called by muse, mutect2
- DNAJC27 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs1442562481, COSV53096056; called by muse, mutect2, varscan2
- DOCK4 | c.2170G>T p.G724C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV101447822; called by muse, mutect2, varscan2
- DPY19L3 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100639156; called by muse, mutect2, varscan2
- DSCAML1 | c.2677C>T p.R893C (on ENST00000321322; = p.R833C on NM_020693.4) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs764993619, COSV58380706; called by muse, mutect2
- DSP | c.6038G>T p.R2013L | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.097); catalogued as COSV101131229; called by muse, mutect2, varscan2
- DYNC2H1 | c.2782G>C p.D928H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100518156; called by muse, mutect2, varscan2
- EFHC1 | c.1081A>G p.I361V | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100931983; called by muse, mutect2, varscan2
- EIF4E1B | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750551455, COSV100024634; called by mutect2, varscan2
- EIF6 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 152/421 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.394); catalogued as COSV99863749; called by muse, mutect2, varscan2
- ELMO1 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100163963; called by muse, mutect2, varscan2
- EML1 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99214789; called by muse, mutect2, varscan2
- ENKD1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99538771; called by muse, mutect2, varscan2
- EXOC2 | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 23/217 reads (11%) | catalogued as COSV100033332, COSV57861489; called by muse, mutect2, varscan2
- EXTL3 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55036850, COSV99593898; called by muse, mutect2, varscan2
- EYS | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100676205, COSV100677103; called by muse, varscan2
- F8 | c.3022G>T p.A1008S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs80201919, COSV100811414, COSV64277818; called by muse, mutect2, varscan2
- FAM153B | c.709G>T p.E237* (on ENST00000253490; = p.E160* on NM_001265615.1) | Nonsense Mutation (SNP) | VAF 60/263 reads (23%) | catalogued as COSV99498862; called by muse, mutect2, varscan2
- FAM83F | c.997T>A p.C333S | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100328902; called by muse, mutect2, varscan2
- FANCE | c.1383+1G>T p.X461_splice | Splice Site (SNP) | VAF 33/102 reads (32%) | catalogued as COSV100003282; called by muse, mutect2, varscan2
- FAT3 | c.12934G>C p.E4312Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs761084058, COSV53089393; called by muse, varscan2
- FBN2 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99326385; called by muse, mutect2, varscan2
- FBXL13 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99978327; called by muse, mutect2, varscan2
- FBXW5 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756947005, COSV56402406; called by muse, mutect2, varscan2
- FER1L6 | c.4487C>A p.P1496H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1251010959, COSV101205717; called by muse, mutect2, varscan2
- FERMT1 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV99451408; called by muse, mutect2, varscan2
- FIBCD1 | c.1050C>A p.F350L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99446936; called by mutect2, varscan2
- FLG | c.7168G>A p.G2390R | Missense Mutation (SNP) | VAF 53/440 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as COSV100911398; called by muse, mutect2, varscan2
- FOXM1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV100700824; called by muse, mutect2, varscan2
- FOXP1 | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs868431423, COSV100561388; called by muse, mutect2, varscan2
- FRMD7 | c.2005G>C p.E669Q | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100048847, COSV100048949; called by muse, mutect2, varscan2
- FSD1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs367820799; called by muse, mutect2, varscan2
- FUT1 | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100038084, COSV59569750; called by muse, mutect2, varscan2
- FUT1 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 48/197 reads (24%) | catalogued as COSV100038086; called by muse, mutect2, varscan2
- FZD10 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV57473557, COSV57474425, COSV99969343; called by muse, mutect2, varscan2
- GABRE | c.401A>T p.N134I | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100944249; called by muse, mutect2, varscan2
- GABRG1 | c.1130C>A p.S377* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV54956064, COSV54963818; called by muse, mutect2
- GALR2 | c.566T>C p.I189T | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100135081; called by muse, mutect2, varscan2
- GAS2 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV99534921; called by muse, mutect2, varscan2
- GATA2 | c.1191C>A p.N397K | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100351148; called by muse, mutect2, varscan2
- GDF7 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs373731959; called by muse, mutect2, varscan2
- GDPD4 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 48/82 reads (59%) | catalogued as COSV60017036; called by muse, mutect2, varscan2
- GK2 | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as COSV62625895; called by muse, mutect2, varscan2
- GLRA2 | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV54336500; called by muse, mutect2, varscan2
- GPR101 | c.1323G>A p.W441* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as rs750658291, COSV99981354; called by muse, mutect2, varscan2
- GPR141 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100550286; called by muse, mutect2, varscan2
- GREM2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs1390968124, COSV100547227, COSV58951193; called by muse, mutect2
- GRHL1 | c.1461+1G>A p.X487_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100257696; called by muse, mutect2, varscan2
- GRIN3A | c.2158T>A p.L720M | Missense Mutation (SNP) | VAF 84/163 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100701444; called by muse, mutect2, varscan2
- GRK3 | c.1173C>G p.F391L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100151352; called by muse, mutect2, varscan2
- GYS1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs933420343, COSV54402838; called by muse, mutect2, varscan2
- H1-2 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59190705, COSV59193232; called by muse, mutect2, varscan2
- HADHB | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100501960; called by muse, mutect2, varscan2
- HDAC9 | c.2894C>A p.S965* | Nonsense Mutation (SNP) | VAF 44/209 reads (21%) | catalogued as COSV101286647; called by muse, mutect2, varscan2
- HGF | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV55946452, COSV55958027, COSV99736401; called by muse, mutect2, varscan2
- HOXA6 | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.334); catalogued as COSV56072748, COSV99762201; called by muse, mutect2, varscan2
- HOXB6 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53312334, COSV99494440; called by muse, mutect2, varscan2
- HPCAL4 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.785); catalogued as rs1478857861, COSV100864765; called by muse, mutect2, varscan2
- HSD3B2 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV101027448; called by muse, mutect2, varscan2
- HYAL2 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99222693; called by muse, mutect2, varscan2
- HYDIN | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.457); catalogued as COSV99862640; called by mutect2, varscan2
- IL16 | c.2678C>A p.P893H (on ENST00000302987 / NM_172217.5; = p.P192H on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100267313; called by muse, mutect2, varscan2
- INPP4B | c.2246G>C p.G749A | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53726630; called by muse, mutect2, varscan2
- INPP5F | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.609); catalogued as COSV100740074; called by muse, mutect2, varscan2
- IPO13 | c.1585A>G p.S529G | Missense Mutation (SNP) | VAF 100/257 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs887638376, COSV100961132; called by muse, mutect2, varscan2
- IQGAP2 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99166954; called by muse, mutect2, varscan2
- IQSEC2 | c.947C>G p.S316C (on ENST00000642864 / NM_001111125.3; = p.S111C on NM_015075.2) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100944820; called by muse, mutect2, varscan2
- IRGC | c.223C>G p.R75G | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99746210; called by muse, mutect2, varscan2
- IRS1 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100524323; called by muse, mutect2, varscan2
- ITGA6 | c.2119G>C p.D707H (on ENST00000442250; = p.D668H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99905304; called by muse, mutect2, varscan2
- ITIH5 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs768283912, COSV53660329; called by muse, mutect2, varscan2
- ITPR2 | c.1859G>T p.S620I | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV101189924; called by muse, mutect2, varscan2
- IVNS1ABP | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100832517; called by muse, mutect2, varscan2
- JAK3 | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as COSV71688418; called by muse, mutect2
- KAT6A | c.3907G>T p.D1303Y | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs1345553292, COSV99704817; called by muse, mutect2, varscan2
- KCNH3 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301009027, COSV57789567; called by muse, mutect2, varscan2
- KCNJ15 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100154127; called by muse, mutect2, varscan2
- KCNJ3 | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99715542; called by muse, mutect2, varscan2
- KCNK16 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767582088, COSV100949158; called by muse, mutect2
- KCNK3 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100256751; called by muse, mutect2, varscan2
- KCNS3 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV100411133; called by muse, mutect2, varscan2
- KCNT1 | c.794C>A p.T265K (on ENST00000488444; = p.T284K on NM_020822.3) | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53694844; called by muse, mutect2, varscan2
- KCTD16 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as rs1408904819, COSV101568779; called by muse, mutect2, varscan2
- KDM3A | c.1205G>C p.R402T | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV100460238, COSV57224405; called by muse, mutect2, varscan2
- KIF5B | c.1305G>C p.K435N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100191718; called by muse, mutect2
- KIRREL3 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101585684; called by muse, mutect2, varscan2
- KLF11 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 23/138 reads (17%) | catalogued as COSV100007713, COSV100007842; called by muse, mutect2, varscan2
- KLHL36 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99256681; called by muse, mutect2, varscan2
- KLK8 | c.198C>A p.N66K | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV99143935; called by muse, mutect2, varscan2
- KMT2B | c.2864C>A p.S955Y | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.67); catalogued as COSV99719265; called by muse, mutect2, varscan2
- KRBA1 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99752470; called by muse, mutect2
- KRT37 | c.823del p.E275Rfs*49 | Frame Shift Del (DEL) | VAF 98/243 reads (40%) | catalogued as COSV56657773; called by mutect2, pindel, varscan2
- KRT6C | c.816+1G>T p.X272_splice | Splice Site (SNP) | VAF 23/170 reads (14%) | catalogued as COSV99359918; called by muse, mutect2, varscan2
- KRT6C | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99359921; called by muse, mutect2, varscan2
- KRTAP10-9 | c.773A>T p.Q258L | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV100552746; called by muse, mutect2
- L3MBTL4 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528332; called by muse, mutect2, varscan2
- LAMA2 | c.866G>T p.C289F | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101370329; called by muse, mutect2, varscan2
- LAMB4 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99223555; called by muse, mutect2, varscan2
- LARP1 | c.958G>C p.D320H (on ENST00000518297 / NM_033551.3; = p.D243H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100303667, COSV60430459; called by muse, mutect2, varscan2
- LDB2 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV100453296, COSV58762604; called by muse, mutect2, varscan2
- LEFTY1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1443931514, COSV55283337, COSV99686476; called by muse, mutect2, varscan2
- LILRB4 | c.72G>T p.G24= | Splice Region (SNP) | VAF 21/91 reads (23%) | catalogued as rs749944629, COSV99553684; called by muse, mutect2, varscan2
- LRIT1 | c.1219C>G p.L407V | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV100928053, COSV64513977; called by muse, mutect2, varscan2
- LRRC8C | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV65002301; called by muse, mutect2, varscan2
- LRRCC1 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100835382; called by muse, mutect2
- LRRK2 | c.5272C>T p.H1758Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54154067; called by muse, mutect2, varscan2
- LYST | c.10778C>A p.T3593K | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV67714964; called by muse, mutect2, varscan2
- MAB21L1 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59777531; called by muse, mutect2, varscan2
- MACF1 | c.3693G>C p.M1231I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100483683; called by muse, mutect2, varscan2
- MAF | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100391770; called by muse, mutect2, varscan2
- MAGEB2 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975630; called by muse, mutect2, varscan2
- MAGEC1 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV53577173; called by muse, mutect2, varscan2
- MAGEL2 | c.2846C>T p.P949L | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV100045854; called by muse, mutect2, varscan2
- MAN2A1 | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs369868516; called by muse, mutect2, varscan2
- MAP1B | c.5902G>T p.E1968* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as COSV57095515, COSV99702129; called by muse, mutect2, varscan2
- MAPK4 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.173); catalogued as COSV101245310, COSV101245513; called by muse, mutect2, varscan2
- MATR3 | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV100735162; called by muse, mutect2, varscan2
- MCL1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.234); catalogued as COSV100329500, COSV57191474; called by muse, mutect2
- MCM3AP | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1216267153, COSV99386753; called by muse, mutect2, varscan2
- MEI1 | c.1713G>C p.L571F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV100299802; called by muse, mutect2, varscan2
- METTL1 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141543; called by muse, mutect2, varscan2
- METTL18 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99609593; called by muse, mutect2, varscan2
- MFAP1 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as COSV99979801; called by muse, mutect2, varscan2
- MFSD9 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV51494903; called by muse, mutect2, varscan2
- MGAT5B | c.1122G>T p.M374I | Missense Mutation (SNP) | VAF 73/128 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as COSV100047725, COSV100048727; called by muse, mutect2, varscan2
- MIS18BP1 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1006945063, COSV100172850; called by muse, mutect2, varscan2
- MROH2B | c.1294A>C p.S432R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV101270623; called by muse, mutect2
- MSH4 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.109); catalogued as COSV99591280; called by muse, mutect2, varscan2
- MTCL1 | c.1606G>C p.E536Q (on ENST00000306329 / NM_001378206.1; = p.E176Q on NM_015210.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100094106, COSV60413859; called by muse, mutect2, varscan2
- MTNR1A | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56155498; called by muse, mutect2, varscan2
- MUC16 | c.39191G>C p.R13064T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.763); catalogued as rs370673116; called by muse, mutect2, varscan2
- MYCBP2 | c.6901G>A p.A2301T (on ENST00000357337; = p.A2339T on NM_015057.5) | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100629824; called by muse, mutect2, varscan2
- MYH14 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.575); catalogued as COSV99222317; called by muse, mutect2, varscan2
- MYLK | c.2692C>T p.R898* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as rs747171137, COSV100658830; called by muse, mutect2, varscan2
- MYO18B | c.860C>A p.A287E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100123207; called by muse, mutect2, varscan2
- MYO18B | c.5287C>A p.Q1763K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100123208; called by muse, mutect2
- MYO1B | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV100268901; called by muse, mutect2, varscan2
- MYO5B | c.3900G>T p.Q1300H | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV99544305; called by muse, mutect2, varscan2
- MYPOP | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100138849; called by muse, mutect2
- NBEA | c.1907G>C p.R636T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100078677, COSV100083713; called by muse, mutect2, varscan2
- NBPF10 | c.11114G>T p.G3705V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs782027497, COSV100744527; called by muse, mutect2, varscan2
- NBPF10 | c.11113G>A p.G3705R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); catalogued as rs781981047, COSV61656555; called by muse, mutect2, varscan2
- NCAM2 | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as COSV99522458; called by muse, mutect2, varscan2
- NCKAP5 | c.2495C>T p.T832I | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.587); catalogued as COSV100491190; called by muse, varscan2
- NCKAP5 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs759744660, COSV100491194, COSV58436806; called by muse, mutect2, varscan2
- NCOA2 | c.4127G>A p.G1376E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99144756; called by muse, mutect2, varscan2
- NEB | c.12058G>T p.V4020L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99419415; called by muse, mutect2, varscan2
- NEB | c.2368G>T p.A790S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); catalogued as COSV99419419; called by muse, mutect2, varscan2
- NFKBIB | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99979322; called by muse, mutect2, varscan2
- NPHS1 | c.2329A>T p.R777* | Nonsense Mutation (SNP) | VAF 56/289 reads (19%) | catalogued as COSV100799724; called by muse, mutect2, varscan2
- NRCAM | c.3252C>G p.I1084M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100694535, COSV61042192; called by muse, mutect2, varscan2
- NTSR1 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs930067057, COSV100980637; called by muse, mutect2, varscan2
- NVL | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV99894032; called by muse, mutect2, varscan2
- OBSCN | c.10600A>T p.R3534W | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52799206, COSV99475995; called by muse, mutect2, varscan2
- OR10A3 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100660251; called by muse, mutect2, varscan2
- OR10G2 | c.570G>T p.L190F | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101606944; called by muse, mutect2, varscan2
- OR1D5 | c.333C>G p.D111E | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as rs778225583, COSV101643417; called by muse, mutect2, varscan2
- OR1J1 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs781369287, COSV99403111; called by muse, mutect2
- OR1K1 | c.886C>A p.R296S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as COSV52956062; called by muse, mutect2, varscan2
- OR2B11 | c.391T>A p.C131S | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100275725; called by muse, mutect2, varscan2
- OR2B3 | c.238C>G p.H80D | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV101013771, COSV65851205; called by muse, varscan2
- OR2B6 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV99773682; called by muse, mutect2, varscan2
- OR2J3 | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101013605; called by muse, mutect2, varscan2
- OR4A15 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100123975; called by muse, mutect2, varscan2
- OR4A15 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 146/223 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.318); catalogued as COSV100123977; called by muse, mutect2, varscan2
- OR4A15 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1263911043, COSV100123978; called by muse, mutect2, varscan2
- OR4E2 | c.916G>T p.V306F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100330061, COSV57731327; called by muse, mutect2, varscan2
- OR51Q1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV56177934; called by muse, mutect2, varscan2
- OR5R1 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 79/122 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100393365, COSV56571992; called by muse, mutect2, varscan2
- OR6C68 | c.223T>A p.C75S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.123); catalogued as COSV101110022; called by muse, mutect2, varscan2
- OR8B12 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 92/143 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100172735; called by muse, mutect2, varscan2
- OSGEPL1 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV99918342; called by muse, mutect2, varscan2
- OTOF | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.43); catalogued as rs1318800399, COSV99717215; called by muse, mutect2, varscan2
- PALM | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as COSV99214426; called by muse, mutect2, varscan2
- PAX9 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.114); catalogued as rs771366081, COSV58718999; called by muse, mutect2, varscan2
- PCDH11Y | c.4005G>T p.M1335I | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99291099; called by muse, mutect2, varscan2
- PCDHB4 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV99522015; called by muse, mutect2, varscan2
- PCDHGA9 | c.1694C>G p.P565R | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1461001534, COSV99535121; called by muse, mutect2, varscan2
- PCYOX1 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99713183; called by muse, mutect2, varscan2
- PDGFRB | c.3259G>C p.E1087Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV99641508; called by muse, mutect2, varscan2
- PES1 | c.652A>T p.R218W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100073086; called by muse, mutect2, varscan2
- PGM5 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101123404; called by muse, mutect2, varscan2
- PGM5 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101123405; called by muse, mutect2, varscan2
- PHKA1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262848; called by muse, mutect2, varscan2
- PI15 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV99477928; called by muse, mutect2, varscan2
- PIGN | c.1323C>G p.F441L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100715688, COSV62948578; called by muse, mutect2, varscan2
- PLAT | c.1139C>G p.P380R | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs748697637, COSV99535086, COSV99535501; called by muse, mutect2, varscan2
- PLCG2 | c.1361A>T p.K454M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV100842165; called by muse, mutect2, varscan2
- PLEKHG4B | c.3289G>T p.D1097Y (on ENST00000283426; = p.D1453Y on NM_052909.5) | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV99360091; called by muse, varscan2
- PLEKHO1 | c.1087T>C p.S363P | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as COSV99215198; called by muse, mutect2, varscan2
- PLXNA4 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.873); catalogued as COSV100323593; called by muse, mutect2, varscan2
- POLE | c.3886G>A p.E1296K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100265970; called by muse, mutect2, varscan2
- POLE | c.3578G>C p.R1193T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100265972; called by muse, mutect2, varscan2
- PPL | c.3973C>G p.L1325V | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as COSV99277769; called by muse, mutect2, varscan2
- PPL | c.3745C>T p.Q1249* | Nonsense Mutation (SNP) | VAF 55/167 reads (33%) | catalogued as COSV99277773; called by muse, mutect2, varscan2
- PPRC1 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs929027213, COSV99531545; called by muse, mutect2, varscan2
- PRDM2 | c.3430C>G p.L1144V | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV99341316; called by muse, mutect2, varscan2
- PREX1 | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100906163; called by muse, mutect2, varscan2
- PRKAA2 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as rs373328629; called by muse, mutect2, varscan2
- PRKACG | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV99598500; called by muse, mutect2, varscan2
- PRMT6 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1163839321, COSV100791168; called by muse, mutect2
- PROS1 | c.728-1G>T p.X243_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as rs368074804, COSV101260374; called by muse, mutect2, varscan2
- PRRC2C | c.3309G>T p.Q1103H (on ENST00000367742; = p.Q1101H on NM_015172.4) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100145036; called by muse, mutect2, varscan2
- PTBP1 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV100608521; called by muse, mutect2, varscan2
- PTCHD4 | c.1805A>G p.N602S | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs772757140, COSV100260540; called by muse, mutect2, varscan2
- PTK2B | c.2366G>T p.S789I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.382); catalogued as COSV100593704; called by muse, mutect2, varscan2
- RAG2 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV100271205; called by muse, mutect2, varscan2
- RBM25 | c.2110G>T p.D704Y | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV99998579; called by muse, mutect2, varscan2
- RBM33 | c.2113A>C p.N705H | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265323; called by muse, mutect2, varscan2
- RCAN1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571632; called by muse, mutect2, varscan2
- RCN2 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV100312745; called by muse, mutect2, varscan2
- RIF1 | c.2908G>C p.E970Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1157838772, COSV99690378; called by muse, mutect2, varscan2
- RIPK3 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs748449238, COSV53477835; called by muse, mutect2, varscan2
- RNF17 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as COSV99692779; called by muse, mutect2, varscan2
- ROR2 | c.2347A>C p.N783H | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100995681; called by muse, mutect2, varscan2
- ROS1 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.66); PolyPhen benign (0.162); catalogued as rs766174223, COSV100876870; called by muse, mutect2, varscan2
- RPL10L | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100022486; called by muse, mutect2, varscan2
- RSKR | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs975883588, COSV56382674; called by muse, mutect2, varscan2
- RYR1 | c.3923C>A p.P1308Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.473); catalogued as COSV100615352; called by muse, mutect2, varscan2
- RYR2 | c.12313C>G p.L4105V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM097969, COSV100769319; called by muse, mutect2, varscan2
- RYR3 | c.6958C>T p.R2320C (on ENST00000389232; = p.R2321C on NM_001036.6) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049547066, COSV63109434; called by muse, mutect2
- SALL3 | c.2451C>G p.D817E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV101609969; called by muse, mutect2, varscan2
- SAMHD1 | c.1547G>C p.R516P (on ENST00000262878 / NM_001363729.2; = p.R551P on NM_015474.4) | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455832; called by muse, mutect2
- SARS1 | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); catalogued as COSV99321114; called by muse, mutect2, varscan2
- SCML4 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100940235; called by muse, mutect2, varscan2
- SECISBP2 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as COSV100368610; called by muse, mutect2, varscan2
- SEMA3D | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99406311; called by muse, mutect2, varscan2
- SERPINE2 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as COSV99296582; called by muse, mutect2, varscan2
- SETBP1 | c.777del p.F260Lfs*83 | Frame Shift Del (DEL) | VAF 35/176 reads (20%) | catalogued as COSV56312772; called by mutect2, varscan2
- SFRP4 | c.592+1G>T p.X198_splice | Splice Site (SNP) | VAF 16/89 reads (18%) | catalogued as COSV101460884; called by muse, mutect2, varscan2
- SGCZ | c.706T>A p.C236S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.297); catalogued as COSV101168205; called by muse, mutect2, varscan2
- SI | c.3308C>A p.S1103* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as COSV52271250, COSV52279533; called by muse, mutect2, varscan2
- SIGLEC8 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100367216, COSV58472028; called by muse, mutect2, varscan2
- SIX2 | c.685C>G p.P229A | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100284139; called by muse, mutect2, varscan2
- SLC12A2 | c.2201C>G p.A734G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV52469967, COSV99320408; called by muse, mutect2, varscan2
- SLC12A9 | c.1549C>G p.L517V | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99307712; called by muse, mutect2, varscan2
- SLC22A16 | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV100397367; called by muse, mutect2, varscan2
- SLC26A5 | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100099005; called by muse, mutect2, varscan2
- SLC29A1 | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100505699; called by muse, mutect2, varscan2
- SLC44A1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101029199; called by muse, mutect2, varscan2
- SLC5A5 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV99714958; called by muse, mutect2, varscan2
- SLCO2A1 | c.1301C>G p.S434* | Nonsense Mutation (SNP) | VAF 119/242 reads (49%) | catalogued as rs1211652982, COSV60486679, COSV60487751; called by muse, mutect2, varscan2
- SLIT3 | c.3214G>C p.E1072Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100266563, COSV60604518; called by muse, mutect2, varscan2
- SMAD2 | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100053551; called by muse, mutect2, varscan2
- SMC4 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100644003; called by muse, mutect2, varscan2
- SMCO3 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV99660621; called by muse, mutect2, varscan2
- SOS2 | c.3380-2A>G p.X1127_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99365803; called by muse, mutect2
- SPATA19 | c.437+1G>A p.X146_splice | Splice Site (SNP) | VAF 37/179 reads (21%) | catalogued as rs1027127732, COSV100141078; called by muse, mutect2, varscan2
- SRD5A1 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 65/95 reads (68%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs1255477361, COSV99944046; called by muse, mutect2, varscan2
- STKLD1 | c.1712C>A p.A571D | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554778209, COSV100905724; called by muse, mutect2, varscan2
- STX7 | c.721A>T p.I241F | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV100908425; called by muse, mutect2, varscan2
- SUGCT | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as COSV100000953, COSV59358024; called by muse, mutect2
- SUPT16H | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99250779; called by muse, mutect2, varscan2
- SUPT16H | c.2857G>C p.D953H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV99250781; called by muse, mutect2, varscan2
- SYCP1 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs772498847, COSV65699764; called by muse, mutect2, varscan2
- SYNJ1 | c.1507C>G p.Q503E | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100449149; called by muse, mutect2, varscan2
- SYNJ1 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100449153, COSV59157353; called by muse, mutect2, varscan2
- SYNPO2 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100205307; called by muse, mutect2, varscan2
- SYT10 | c.959A>G p.D320G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99951187; called by muse, mutect2
- SZT2 | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV100987050; called by muse, mutect2
- TAF4 | c.1870G>T p.V624L | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1298781954, COSV99433903; called by muse, mutect2, varscan2
- TAPBP | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101444930; called by muse, mutect2, varscan2
- TAS2R20 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as COSV67864108; called by muse, mutect2, varscan2
- TBC1D22A | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100452851; called by muse, mutect2, varscan2
- TBC1D8B | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99344160; called by muse, mutect2, varscan2
- TBC1D9B | c.1863G>C p.E621D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100783485; called by muse, mutect2, varscan2
- TBC1D9B | c.1862A>G p.E621G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62281250; called by muse, mutect2
- TENM3 | c.1697G>T p.C566F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101305009; called by muse, mutect2, varscan2
- TENM4 | c.4117G>C p.D1373H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99573013; called by muse, mutect2, varscan2
- TGM4 | c.227T>A p.V76E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99942233; called by muse, mutect2, varscan2
- THRAP3 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1263049028, COSV100663302, COSV100663327; called by muse, mutect2, varscan2
- THSD7A | c.1888C>A p.P630T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101448618; called by muse, mutect2
- TIAM1 | c.2221G>T p.E741* | Nonsense Mutation (SNP) | VAF 34/138 reads (25%) | catalogued as COSV99734227; called by muse, mutect2, varscan2
- TINAG | c.1314G>T p.W438C | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99449154; called by muse, mutect2, varscan2
- TMEM132D | c.2594A>G p.K865R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV101242707, COSV67158649; called by muse, mutect2, varscan2
- TMEM200A | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.235); catalogued as COSV99759004; called by muse, mutect2
- TNN | c.2277G>C p.Q759H | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV53423218, COSV53424598; called by muse, mutect2, varscan2
- TNR | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV99688816; called by muse, mutect2, varscan2
- TNR | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.741); catalogued as COSV99688818; called by muse, mutect2, varscan2
- TOM1 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV101146665; called by muse, mutect2, varscan2
- TRAF3IP3 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99160735; called by muse, mutect2, varscan2
- TRIM10 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as rs759629347, COSV64989617; called by muse, mutect2, varscan2
- TRIOBP | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.205); catalogued as rs748198724, COSV100730775; called by muse, varscan2
- TRNT1 | c.939G>C p.L313F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV99214134; called by muse, mutect2, varscan2
- TRPC3 | c.1523C>A p.T508K (on ENST00000379645 / NM_001366479.2; = p.T435K on NM_003305.2) | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99312434; called by muse, mutect2, varscan2
- TRPC5 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as COSV99460261; called by muse, mutect2, varscan2
- TSHZ3 | c.2178G>T p.Q726H | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99551169; called by muse, mutect2, varscan2
- TSPAN12 | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763110, COSV99763404; called by muse, mutect2, varscan2
- TTN | c.83491A>G p.I27831V (on ENST00000591111; = p.I20407V on NM_003319.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | PolyPhen benign (0.203); catalogued as COSV100604293; called by muse, varscan2
- TTN | c.35804C>T p.P11935L (on ENST00000591111; = p.P4511L on NM_003319.4) | Missense Mutation (SNP) | VAF 33/157 reads (21%) | PolyPhen benign (0.025); catalogued as COSV100604296, COSV60093016; called by muse, mutect2, varscan2
- UBASH3A | c.1585C>A p.L529M | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.674); catalogued as COSV99369454; called by muse, mutect2, varscan2
- UBASH3B | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99417364; called by muse, mutect2, varscan2
- UBC | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV100298902; called by muse, varscan2
- UBXN10 | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV100907761, COSV66771876; called by muse, mutect2, varscan2
- UGT3A1 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV99954586; called by muse, mutect2
- USH2A | c.2669C>T p.T890I | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs771083549, COSV100232567, COSV100238644; called by muse, mutect2, varscan2
- UTP14A | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV100928948; called by muse, mutect2, varscan2
- VARS1 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 125/351 reads (36%) | catalogued as COSV100989919; called by muse, mutect2, varscan2
- VTN | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782168976, COSV56873761; called by muse, mutect2, varscan2
- WARS1 | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV100690115; called by muse, mutect2, varscan2
- WFIKKN2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs777517936, COSV60957989; called by muse, mutect2, varscan2
- WNK1 | c.1643A>T p.E548V | Missense Mutation (SNP) | VAF 177/315 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100266938; called by muse, mutect2, varscan2
- WWP2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs546382050, COSV100598510; called by muse, varscan2
- XIRP2 | c.3940C>A p.Q1314K (on ENST00000628543; = p.Q1489K on NM_152381.6) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV99741189; called by muse, mutect2, varscan2
- XPO5 | c.2487C>G p.F829L | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV99540703; called by muse, mutect2
- YES1 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs986350587, COSV58851731; called by muse, mutect2, varscan2
- ZBBX | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100283694; called by muse, mutect2, varscan2
- ZBED9 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV71729287; called by muse, mutect2, varscan2
- ZBTB20 | c.1123T>G p.F375V (on ENST00000474710 / NM_001164342.2; = p.F302V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100613394; called by muse, mutect2, varscan2
- ZFHX4 | c.1334G>A p.C445Y | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV99260936; called by muse, mutect2, varscan2
- ZFPM2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV65873093; called by muse, mutect2, varscan2
- ZNF221 | c.192G>T p.R64S | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV99240649; called by muse, mutect2, varscan2
- ZNF318 | c.4218C>G p.I1406M | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100546081, COSV100546166; called by muse, mutect2, varscan2
- ZNF318 | c.3960C>G p.I1320M | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100546083; called by muse, mutect2, varscan2
- ZNF337 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs201475832, COSV99430121; called by muse, mutect2, varscan2
- ZNF462 | c.6169A>G p.K2057E | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99471363; called by muse, mutect2, varscan2
- ZNF536 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as COSV100834991; called by muse, mutect2
- ZNF577 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV100030947; called by muse, mutect2, varscan2
- ZNF583 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99382047; called by muse, mutect2, varscan2
- ZNF599 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV61395422; called by muse, mutect2, varscan2
- ZNF681 | c.357G>C p.E119D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs766381947, COSV101267431; called by muse, mutect2, varscan2
- ZSCAN18 | c.1228G>T p.G410W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53729637, COSV99559285; called by muse, mutect2, varscan2
- ZSCAN31 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.56); catalogued as COSV100716942; called by muse, mutect2, varscan2
- ADGRF2 | c.1902_1913del p.I634_S637del (on ENST00000296862 / NM_001368115.2; = p.I566_S569del on NM_153839.7) | In Frame Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- APOBEC3B | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ATF7IP | c.657dup p.I220Hfs*4 | Frame Shift Ins (INS) | VAF 58/159 reads (36%) | called by pindel, varscan2
- BCAP31 | c.532del p.E178Rfs*7 | Frame Shift Del (DEL) | VAF 76/383 reads (20%) | called by mutect2, pindel, varscan2
- CHST2 | c.440del p.A147Gfs*74 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- DOP1B | c.205del p.Q69Sfs*13 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | called by mutect2, pindel*, varscan2
- IGHG3 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 12/327 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV2D-24 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ITGA4 | c.1020dup p.V341Cfs*22 | Frame Shift Ins (INS) | VAF 42/181 reads (23%) | called by mutect2, pindel, varscan2
- LIM2 | c.217del p.L73Yfs*77 (on ENST00000596399 / NM_001161748.2; = p.L115Yfs*77 on NM_030657.4) | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by mutect2, pindel, varscan2
- MIA2 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2
- RIMBP3 | c.4222C>A p.Q1408K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SIX5 | c.462dup p.A155Rfs*17 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1414C>A p.P472T | Missense Mutation (SNP) | VAF 265/675 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AKT3 | c.1245T>C p.D415= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99794911; called by muse, mutect2, varscan2
- ALDH16A1 | c.1200G>T p.P400= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV104394621, COSV99512767; called by muse, mutect2, varscan2
- ALDH1L2 | c.2670G>A p.A890= | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as rs930807837, COSV51559815; called by muse, mutect2, varscan2
- ANXA8 | c.306G>A p.L102= | Silent (SNP) | VAF 88/203 reads (43%) | called by muse, mutect2, varscan2
- ARSF | c.424T>C p.L142= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100839472; called by muse, mutect2, varscan2
- ASTN2 | c.3090G>C p.L1030= (on ENST00000313400 / NM_001365069.1; = p.L979= on NM_014010.5) | Silent (SNP) | VAF 33/263 reads (13%) | catalogued as COSV99940558; called by muse, mutect2, varscan2
- ATP8A2 | c.2289C>T p.I763= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV99681216; called by muse, mutect2, varscan2
- ATP8B1 | c.1188C>T p.L396= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV99377112, COSV99377413; called by muse, varscan2
- ATP8B1 | c.1119C>T p.L373= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99377113; called by muse, varscan2
- B2M | c.129G>A p.L43= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as COSV100837628; called by muse, mutect2, varscan2
- B3GALNT2 | c.1461G>C p.L487= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV100782791; called by muse, mutect2, varscan2
- C1orf141 | c.567C>T p.V189= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV100924314; called by muse, mutect2, varscan2
- CARMIL1 | c.2361G>A p.E787= | Silent (SNP) | VAF 43/264 reads (16%) | catalogued as COSV100277427; called by muse, mutect2, varscan2
- CATSPER4 | c.66C>A p.G22= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100128301; called by muse, mutect2, varscan2
- CD36 | c.1137C>T p.F379= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99987381; called by muse, mutect2, varscan2
- CD86 | c.96C>T p.F32= (on ENST00000330540 / NM_175862.5; = p.F26= on NM_006889.4) | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100053902; called by muse, mutect2, varscan2
- CDHR3 | c.2487G>C p.G829= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs747895280, COSV100488180; called by muse, mutect2, varscan2
- CHRM5 | c.462C>A p.A154= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as COSV101271895; called by muse, mutect2, varscan2
- CIB3 | c.318C>T p.L106= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs1190306482, COSV99521759; called by muse, mutect2, varscan2
- COL6A6 | c.1641C>A p.G547= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as rs368961411; called by muse, mutect2
- COL9A1 | c.1209C>A p.G403= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100294475; called by muse, mutect2, varscan2
- CRY1 | c.99C>T p.C33= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99150568; called by muse, mutect2, varscan2
- CSMD2 | c.7134C>T p.P2378= | Silent (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- CTSB | c.897C>G p.S299= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs147857910, COSV100565837; called by muse, mutect2, varscan2
- DNAH11 | c.3633C>G p.V1211= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1172314293, COSV100178501; called by muse, mutect2
- DNAH8 | c.9252C>T p.L3084= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100544268; called by muse, mutect2, varscan2
- DOCK2 | c.2367C>A p.I789= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV99911422; called by muse, mutect2, varscan2
- EFCAB11 | c.348C>T p.F116= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV99965585; called by muse, mutect2, varscan2
- FAM131B | c.924C>T p.L308= | Silent (SNP) | VAF 74/320 reads (23%) | catalogued as COSV100577924, COSV58372307; called by muse, mutect2, varscan2
- FAM47A | c.756C>A p.P252= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100649809; called by muse, mutect2, varscan2
- FAM83F | c.996C>A p.G332= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100328901; called by muse, mutect2, varscan2
- FGF21 | c.558C>A p.P186= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99711422; called by muse, mutect2, varscan2
- GDA | c.420T>C p.C140= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99429040; called by muse, mutect2, varscan2
- GFRAL | c.988T>C p.L330= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1327712940, COSV61232221; called by muse, mutect2, varscan2
- GLIPR2 | c.168G>A p.P56= | Silent (SNP) | VAF 32/52 reads (62%) | catalogued as rs138525625; called by muse, mutect2, varscan2
- GOLGA1 | c.1710G>A p.L570= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV100764443; called by muse, mutect2, varscan2
- GON4L | c.2616C>T p.N872= | Silent (SNP) | VAF 19/218 reads (9%) | catalogued as COSV99673950; called by muse, mutect2
- GON4L | c.2286G>A p.L762= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV99673955, COSV99675580; called by muse, mutect2, varscan2
- H2AC13 | c.309C>T p.I103= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV100704353; called by muse, mutect2, varscan2
- H3C2 | c.108G>A p.V36= | Silent (SNP) | VAF 57/371 reads (15%) | catalogued as rs759554988, COSV99451433; called by muse, mutect2, varscan2
- IBSP | c.390C>A p.I130= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV99883482; called by muse, mutect2, varscan2
- IGKV1D-42 | c.45C>T p.L15= | Silent (SNP) | VAF 54/289 reads (19%) | catalogued as rs370275944; called by muse, mutect2, varscan2
- IL25 | c.81C>A p.V27= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV100197995; called by muse, mutect2, varscan2
- INSC | c.177C>G p.S59= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV101088985, COSV65412969; called by muse, mutect2, varscan2
- IQGAP2 | c.945G>C p.P315= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV57171336, COSV99166950; called by muse, mutect2, varscan2
- IQGAP2 | c.1899A>G p.S633= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV99166959; called by muse, mutect2
- ITGA6 | c.1176C>T p.V392= (on ENST00000442250; = p.V353= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99905300; called by muse, mutect2, varscan2
- KCNQ3 | c.903G>A p.E301= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as rs764285990, COSV101195883; called by muse, mutect2, varscan2
- KRT2 | c.660C>A p.T220= | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as COSV100548394; called by muse, mutect2, varscan2
- KRT83 | c.69C>T p.C23= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as rs747188137, COSV99531275; called by muse, mutect2, varscan2
- KRTAP13-2 | c.264C>T p.L88= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV101299630; called by muse, mutect2, varscan2
- LAMA1 | c.8967C>T p.I2989= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs768389055, COSV101055823; called by muse, mutect2, varscan2
- LDHC | c.924G>A p.L308= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV99772416; called by muse, mutect2, varscan2
- LEPR | c.3348C>A p.L1116= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as COSV100848092; called by muse, mutect2, varscan2
- LGI2 | c.1581C>T p.S527= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV101180801; called by muse, mutect2
- MMP26 | c.612G>C p.L204= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100332036, COSV56172433; called by muse, mutect2, varscan2
- MYOCD | c.2658C>A p.P886= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV58505134; called by muse, mutect2, varscan2
- MYT1L | c.1740G>T p.L580= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV101219936; called by muse, mutect2, varscan2
- NAP1L3 | c.1050T>A p.P350= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as COSV100220278; called by muse, mutect2, varscan2
- NCKAP5 | c.2496T>C p.T832= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as COSV100491189; called by muse, varscan2
- NECTIN1 | c.387C>T p.F129= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as rs770372133, COSV99871971; called by muse, mutect2, varscan2
- OR10J3 | c.402A>C p.S134= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as COSV100171685; called by muse, mutect2
- OR10S1 | c.705C>T p.I235= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs370872807; called by muse, mutect2, varscan2
- OR11L1 | c.819C>A p.I273= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100869410, COSV63313737; called by muse, mutect2, varscan2
- OR1S1 | c.93C>T p.F31= | Silent (SNP) | VAF 88/221 reads (40%) | catalogued as rs879234146, COSV100515338; called by muse, mutect2, varscan2
- OR2L13 | c.456C>A p.S152= | Silent (SNP) | VAF 74/374 reads (20%) | catalogued as COSV100813714; called by muse, mutect2, varscan2
- OR4Q3 | c.900T>C p.N300= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV100056921; called by muse, mutect2, varscan2
- OR51I1 | c.720C>G p.L240= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100971086; called by muse, mutect2, varscan2
- OR8I2 | c.372A>T p.I124= | Silent (SNP) | VAF 101/166 reads (61%) | catalogued as COSV100135993; called by muse, mutect2, varscan2
- PANK2 | c.1153C>T p.L385= (on ENST00000316562 / NM_153638.3; = p.L94= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs760986960, CX101232, COSV100262219; called by muse, mutect2, varscan2
- PARD3 | c.3147A>C p.S1049= | Silent (SNP) | VAF 76/155 reads (49%) | catalogued as COSV100631533; called by muse, mutect2, varscan2
- PAX6 | c.1005C>T p.F335= | Silent (SNP) | VAF 75/184 reads (41%) | catalogued as COSV99570301; called by muse, mutect2, varscan2
- PCDH7 | c.2418C>A p.T806= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- PDE1C | c.1458T>A p.S486= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV100371994; called by muse, mutect2, varscan2
- PEX14 | c.237C>T p.S79= | Silent (SNP) | VAF 82/188 reads (44%) | catalogued as COSV100750067; called by muse, mutect2, varscan2
- PKNOX2 | c.9A>G p.Q3= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100020601; called by muse, mutect2
- PLCB4 | c.1299G>A p.L433= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99595005; called by muse, mutect2, varscan2
- PLXNB1 | c.1965C>G p.V655= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99602630; called by muse, mutect2, varscan2
- PRKDC | c.10023C>T p.L3341= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100039663; called by muse, mutect2, varscan2
- PTGER4 | c.295C>T p.L99= | Silent (SNP) | VAF 38/516 reads (7%) | catalogued as COSV100201500; called by muse, mutect2
- PTPRB | c.2700C>T p.F900= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99716777; called by muse, mutect2, varscan2
- REST | c.1200G>A p.K400= | Silent (SNP) | VAF 49/167 reads (29%) | catalogued as COSV100470855; called by muse, mutect2, varscan2
- RHEB | c.384G>T p.V128= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100062045; called by mutect2, varscan2
- RNASE2 | c.43C>T p.L15= | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as COSV100482038; called by muse, mutect2, varscan2
- RSF1 | c.2187G>A p.Q729= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as COSV100407064; called by muse, mutect2, varscan2
- RTN3 | c.546A>G p.K182= (on ENST00000377819 / NM_001265589.2; = p.K163= on NM_201428.3) | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV100127408; called by muse, mutect2, varscan2
- SALL1 | c.1710C>T p.I570= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV99173101; called by muse, mutect2, varscan2
- SERPINA9 | c.498C>T p.S166= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as COSV100098207; called by muse, mutect2, varscan2
- SF3B3 | c.2523A>T p.A841= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV100209750; called by muse, mutect2, varscan2
- SIPA1L1 | c.396G>T p.L132= | Silent (SNP) | VAF 47/195 reads (24%) | catalogued as COSV100665375; called by muse, mutect2, varscan2
- SLC14A2 | c.2187C>A p.S729= | Silent (SNP) | VAF 117/276 reads (42%) | catalogued as COSV99675325; called by muse, mutect2, varscan2
- SLC25A37 | c.450G>T p.G150= | Silent (SNP) | VAF 46/233 reads (20%) | catalogued as COSV99263906; called by muse, mutect2, varscan2
- SLC35D2 | c.400C>T p.L134= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99480779; called by muse, mutect2, varscan2
- SLITRK2 | c.120C>T p.N40= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV59427014; called by muse, mutect2
- SNTG1 | c.18C>A p.A6= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99382848; called by muse, mutect2, varscan2
- STAB2 | c.1800C>T p.A600= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs200307097, COSV101185811, COSV101186139; called by muse, mutect2, varscan2
- SYNE3 | c.1458G>T p.L486= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as COSV100515858; called by muse, mutect2, varscan2
- TARS1 | c.1224G>A p.L408= | Silent (SNP) | VAF 10/213 reads (5%) | catalogued as COSV54311598, COSV99465760; called by muse, mutect2
- TBX15 | c.318C>T p.A106= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99253918; called by muse, mutect2, varscan2
- TCHH | c.5292G>T p.L1764= | Silent (SNP) | VAF 74/213 reads (35%) | catalogued as COSV100914963; called by muse, mutect2, varscan2
- TDRD5 | c.1524C>T p.R508= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as COSV99675918; called by muse, mutect2
- THSD7B | c.309C>G p.L103= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99747950, COSV99750059; called by muse, mutect2, varscan2
- TLR4 | c.2337C>T p.L779= (on ENST00000355622 / NM_138554.5; = p.L739= on NM_003266.4) | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as COSV100842721, COSV62922906, COSV62923349; called by muse, mutect2, varscan2
- TMEM186 | c.399G>A p.L133= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV51631234, COSV99191124; called by muse, mutect2, varscan2
- TMIGD1 | c.570C>T p.N190= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as rs758219700, COSV100187195; called by muse, mutect2, varscan2
- TPO | c.1002G>T p.P334= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV61099582, COSV61102669; called by muse, mutect2, varscan2
- TRAV14DV4 | c.300C>A p.S100= | Silent (SNP) | VAF 47/189 reads (25%) | called by muse, mutect2, varscan2
- TRMT61B | c.45G>T p.R15= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV100066500, COSV60257995; called by muse, mutect2
- TTF2 | c.1374C>A p.T458= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs1295136182, COSV101037380; called by muse, mutect2, varscan2
- TWNK | c.129G>A p.E43= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV99272237; called by muse, mutect2, varscan2
- TXLNB | c.1614C>G p.L538= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as rs759827745, COSV100624908; called by muse, mutect2, varscan2
- UBE3B | c.78G>A p.Q26= | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as COSV99783889; called by muse, mutect2, varscan2
- USH2A | c.14871G>A p.L4957= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100232566; called by muse, mutect2, varscan2
- USP20 | c.696C>T p.T232= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100204214; called by muse, mutect2, varscan2
- USP24 | c.6024C>T p.C2008= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs1286436604, COSV99599366; called by muse, mutect2, varscan2
- YTHDC1 | c.1326C>G p.V442= (on ENST00000344157 / NM_001031732.4; = p.V424= on NM_133370.4) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100704659; called by muse, mutect2, varscan2
- ZDHHC11 | c.960G>A p.L320= | Silent (SNP) | VAF 32/317 reads (10%) | catalogued as rs1439244282, COSV99362546; called by muse, mutect2, varscan2
- ZNF530 | c.1140G>A p.E380= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV100252476; called by muse, mutect2, varscan2
- ZNF536 | c.213C>A p.P71= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as COSV100834990, COSV62831129; called by muse, mutect2, varscan2
- ZSCAN1 | c.1057C>A p.R353= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV56603506, COSV56605032, COSV99991543; called by muse, mutect2, varscan2
- ANKS1B | c.2420-52C>A | Intron (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100227631, COSV100228645; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-211A>T | Intron (SNP) | VAF 49/149 reads (33%) | called by muse, mutect2, varscan2
- DCHS2 | n.4656G>T | RNA (SNP) | VAF 34/134 reads (25%) | catalogued as rs1482644065, COSV100601501; called by muse, mutect2, varscan2
- HERC2P3 | n.845C>A | RNA (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5560G>A | Intron (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99633486; called by muse, mutect2, varscan2
- PAX2 | c.1090+215C>A | Intron (SNP) | VAF 46/99 reads (46%) | catalogued as COSV100695113; called by muse, mutect2, varscan2
- PRDM15 | c.-560G>C | 5'UTR (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99519823; called by muse, mutect2, varscan2
- PRKACB | c.47-34658C>G | Intron (SNP) | VAF 94/217 reads (43%) | catalogued as rs1407369853, COSV100854885; called by muse, mutect2, varscan2
- PTN | c.-117G>T | 5'UTR (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100780818; called by muse, mutect2, varscan2
- SIKE1 | c.159+9G>A | Intron (SNP) | VAF 26/178 reads (15%) | catalogued as COSV99285221; called by muse, mutect2, varscan2
